Surgical pathology report (de-identified scan), TCGA case TCGA-06-0189, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0189-01A (Primary Tumor).

[page 1 of 3]
TCGA-06-0189

Surgical Pathology Report

CLINICAL HISTORY

[REDACTED] with headache and nausea for about [REDACTED], has right temporal necrotic, hemorrhagic and enhancing tumor, and right middle cerebral artery aneurysm.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, resection

B: Brain, resection

PATHOLOGICAL DIAGNOSIS:

A. Brain, site not specified, excision: Glioblastoma.
See comment.

COMMENT

The specimen is brain diffusely infiltrated and focally effaced by an astrocytic neoplastic process with nuclear anaplasia, mitoses, microvascular cellular proliferation, and extensive areas of necrosis.

Special stains to better characterize the neoplasm have been requested, and will be reported as an addendum.

PROCEDURES/ADDENDA

Addendum

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Addendum Diagnosis

A. Brain, MIB-1 proliferation index: 12%.
B. Brain, site not specified, excision: Glioblastoma.
See comment.

Addendum Comment

In part A, the MIB-1 proliferation index is about 12%.

In part B, there are fragments of brain extensively infiltrated and focally effaced by a glioblastoma with extensive zones of necrosis. The neoplasm seems to be present in the leptomeningeal space.

[page 2 of 3]
GROSS DESCRIPTION:

TC6A-06-0189

B.

SPECIMEN: Brain tumor.

FIXATIVE: None.

GENERAL: Received is a 5.0 x 4.0 x 1.5 cm aggregate of tan-brown fragments of soft tissue admixed with clotted blood. The specimens are serially sectioned to reveal a uniform cut surface.

SECTIONS: Entirely submitted in cassettes B1-B4.

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates glial fibrillogenesis by the neoplastic cells. Over 2/3rds of the neoplastic cells over express the p53 protein. With the MIB-1 there is a proliferation index of about 12% in the more active areas of the neoplasm.

These immuno results support a diagnosis of a high histological grade glioma.

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Received paraffin sections labeled [REDACTED] [REDACTED] [REDACTED].

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

INTRA-OPERATIVE CONSULTATION

Brain, resection, smears and frozen sections: Glioma, one block, [REDACTED].

GROSS DESCRIPTION

A. Multiple tissue fragments, 0.3 to 0.5 cm. All in A1, A2

[page 3 of 3]
ICD-9(s):
348.8 348.8

TCGA-06-0189

Histo Data

Part A: Brain, resection

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
H/E x 1		1		
H/E x 1		1B		
mGFAP-DA x 1		2		
H/E x 1		2		
MGMT x 1		2		
MIB1-DA x 1		2		
P53DO7 x 1		2		
H/E x 1		2B		
H/E x 1		3B		
H/E x 1		4B		

Part B: Brain, resection

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
H/E x 1		1		
H/E x 1		2		
H/E x 1		3		
H/E x 1		4		

*** End of Report ***

Source: NCI Genomic Data Commons file 0aaf8254-7188-4420-8d60-d5b698262cf2 (TCGA-06-0189.EAB1F4F5-081A-4396-B2E1-496E6E71FF7D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).